Gene-level copy-number profile of tumor specimen C3L-01252-01 from CPTAC case C3L-01252, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 76.8 years (28,034 days).
Specimen C3L-01252-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c09135ff-3180-4285-9553-d787e5cf2869.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01252-72 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/02a213f1-6e11-4c31-96ff-bc32fd4320ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 117; copy number 2: 58,235; copy number 3: 7; copy number 5: 13; copy number 7: 9; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–149,556,361, 4 genes: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr1:149,676,851–149,747,818, 2 genes (within-gene range 0–1): AC243772.3, RNU1-68P.
- chr10:79,841,358–79,850,878, 1 gene: NUTM2E.
- chr10:93,881,293–93,881,938, 1 gene: RAB11AP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes, copy number 7: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:266,855–594,768, 10 genes, copy number 5: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1.
- chr1:631,074–632,616, 2 genes, copy number 5 (within-gene range 2–5): MTCO1P12, AC114498.2.
- chr1:633,535–633,741, 1 gene, copy number 5 (within-gene range 2–5): MTATP8P1.
- chr1:143,498,785–143,500,512, 2 genes, copy number 11: AC239859.2, LINC02799.

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
